Somatic mutation profile of tumor specimen TCGA-GV-A40G-01A (aliquot TCGA-GV-A40G-01A-11D-A23M-08) from TCGA case TCGA-GV-A40G, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 77.2 years (28,204 days).
Specimen TCGA-GV-A40G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f04e8e0-5ad5-47e8-b59d-4f8938007e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A40G-10A (Blood Derived Normal), aliquot TCGA-GV-A40G-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7432be91-fcc3-444c-a974-3c35d98b2ef2

The open-access MAF lists 170 somatic variants for this specimen: 122 protein-altering or splice-affecting, 43 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 43, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 3, RNA 3, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2663+2T>C p.X888_splice | Splice Site (SNP) | VAF 28/107 reads (26%) | catalogued as rs587778839, COSV57296597, COSV57312328; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121912667, CM083790, COSV52676438, COSV53038615, COSV53625652; ClinVar: pathogenic; called by muse, varscan2
- ABCG4 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); catalogued as rs1367006399, COSV56642075; called by muse, mutect2, varscan2
- ABHD11 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV56105223; called by muse, mutect2, varscan2
- ABHD15 | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV56194738; called by muse, mutect2, varscan2
- ABRAXAS2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV53715994, COSV53717869; called by muse, mutect2, varscan2
- ACOT7 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV64111878, COSV64113569; called by muse, mutect2, varscan2
- AP3D1 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV61424616; called by muse, mutect2, varscan2
- ARID2 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57594813; called by muse, mutect2, varscan2
- ATP13A4 | c.2107T>G p.L703V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs951027898, COSV61316391; called by muse, mutect2, varscan2
- AUTS2 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61383868; called by muse, mutect2
- AVL9 | c.761G>C p.S254T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV59464202; called by muse, mutect2, varscan2
- C19orf54 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184492176, COSV99648819; called by muse, mutect2, varscan2
- C2CD2 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs777276877, COSV61598810; called by muse, mutect2, varscan2
- CALML6 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV57068737; called by muse, mutect2, varscan2
- CAMTA2 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV61833148; called by muse, mutect2, varscan2
- CCDC78 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs769448022, COSV52400804; called by muse, mutect2, varscan2
- CD207 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69651660; called by muse, mutect2, varscan2
- CD33 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51800007; called by muse, mutect2, varscan2
- CDC42BPB | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63473918; called by muse, mutect2, varscan2
- CDH23 | c.9088A>G p.M3030V | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV56448863; called by muse, mutect2, varscan2
- CEMP1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.934); catalogued as rs774433891, COSV53549683; called by muse, mutect2, varscan2
- CHAMP1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV63521759; called by muse, mutect2, varscan2
- CHRND | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.932); catalogued as COSV51317422; called by muse, mutect2, varscan2
- CLEC4M | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50216795; called by muse, mutect2, varscan2
- CRACDL | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV67406576; called by muse, mutect2, varscan2
- CYP2E1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53312202; called by muse, mutect2, varscan2
- DCLK2 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56199715; called by muse, mutect2, varscan2
- DHRSX | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 121/232 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs149133886, COSV58130209; called by muse, mutect2, varscan2
- DHRSX | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58130227; called by muse, mutect2, varscan2
- DNAH8 | c.829A>G p.N277D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59425893; called by muse, mutect2, varscan2
- DSG2 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as CD061400, COSV99853414; called by muse, mutect2
- DYNC1I1 | c.248G>A p.W83* | Nonsense Mutation (SNP) | VAF 50/88 reads (57%) | catalogued as COSV61458190; called by muse, mutect2, varscan2
- ERBB2 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 113/165 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV54063501, COSV54069910; called by muse, mutect2, varscan2
- ETV7 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs145392208, COSV60316040; called by muse, mutect2, varscan2
- F5 | c.4960G>A p.D1654N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63120734; called by muse, mutect2, varscan2
- FASTKD2 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV52697436; called by muse, mutect2
- FAT3 | c.5969C>T p.S1990L | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.674); catalogued as COSV53077188; called by muse, mutect2, varscan2
- FER1L5 | c.5474C>T p.A1825V (on ENST00000623019; = p.A1789V on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs755967439, COSV53840595; called by muse, mutect2, varscan2
- FLG2 | c.5751G>C p.K1917N | Missense Mutation (SNP) | VAF 69/627 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.242); catalogued as COSV66166737; called by muse, mutect2, varscan2
- GABPA | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV61395404; called by muse, mutect2, varscan2
- GALNT8 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52894715; called by muse, mutect2, varscan2
- GEMIN7 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV54319212; called by muse, mutect2, varscan2
- GHR | c.266G>T p.R89M | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM930310, COSV50106452; called by muse, mutect2, varscan2
- GLRA1 | c.1097G>C p.G366A (on ENST00000455880 / NM_001146040.2; = p.G358A on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.103); catalogued as COSV51007602; called by muse, mutect2, varscan2
- HEXD | c.1285G>A p.E429K (on ENST00000327949 / NM_001369487.1; = p.R458= on NM_173620.3) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.169); catalogued as rs373845503; called by muse, mutect2, varscan2
- HTRA2 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.836); catalogued as COSV51206168, COSV51212169; called by muse, mutect2, varscan2
- HYDIN | c.15199G>A p.E5067K | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV66637250; called by muse, mutect2, varscan2
- ICE2 | c.2152G>C p.D718H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748640801, COSV55029749; called by muse, mutect2
- IL7R | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1057520828, COSV57405909; ClinVar: likely benign; called by muse, mutect2
- IQGAP3 | c.4181C>T p.S1394F | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV63249466; called by muse, mutect2, varscan2
- ITGA2B | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs375195998; called by muse, mutect2, varscan2
- JADE2 | c.1438A>G p.R480G | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50911504; called by muse, mutect2, varscan2
- KCNA10 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141128096; called by muse, mutect2
- KRT38 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs749811097, COSV55845227; called by muse, mutect2
- LAMA2 | c.4311+2T>C p.X1437_splice | Splice Site (SNP) | VAF 5/81 reads (6%) | catalogued as COSV70338973; called by muse, mutect2
- LRRC7 | c.1570G>A p.E524K (on ENST00000651989 / NM_001370785.2; = p.E491K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs866086728, COSV50412443; called by muse, mutect2, varscan2
- MEGF8 | c.5858G>A p.R1953H (on ENST00000251268 / NM_001271938.2; = p.R1886H on NM_001410.3) | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.661); catalogued as rs771233244, COSV52075498; called by muse, mutect2, varscan2
- MRPL11 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759516886, COSV60598375; called by muse, mutect2, varscan2
- MSMO1 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54969623; called by muse, mutect2, varscan2
- MSMO1 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.324); catalogued as COSV54969637; called by muse, mutect2, varscan2
- MYOM2 | c.1269A>C p.E423D | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV50702422; called by muse, varscan2
- MYT1L | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV101221143, COSV67714103; called by muse, varscan2
- NCKAP5 | c.2133G>T p.E711D | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV58428023; called by muse, mutect2, varscan2
- NKIRAS2 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1379044285; called by muse, mutect2, varscan2
- NLRP7 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.959); catalogued as COSV60171199; called by muse, mutect2, varscan2
- NMBR | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV57800434; called by muse, mutect2, varscan2
- NR1H2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53799899; called by muse, mutect2, varscan2
- NR4A1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54479983; called by muse, mutect2, varscan2
- NUP155 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV51527101; called by muse, mutect2, varscan2
- OR10A2 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV56298704; called by muse, mutect2, varscan2
- OR4C13 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV73648631, COSV73648917; called by muse, mutect2
- OR4C3 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs369587361, COSV60586597; called by muse, mutect2, varscan2
- OR4X2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56582260; called by muse, mutect2, varscan2
- PCDHA9 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV65323577; called by muse, mutect2, varscan2
- POU6F2 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV68867762; called by muse, mutect2, varscan2
- PREX2 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV55751525; called by muse, mutect2, varscan2
- PROCA1 | c.431G>A p.R144Q (on ENST00000439862 / NM_001366301.1; = p.R116Q on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1318633969, COSV56385321; called by muse, mutect2, varscan2
- PROS1 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM011466, COSV67774305; called by muse, mutect2, varscan2
- PRSS48 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs1286042388, COSV71613538; called by muse, mutect2
- PYDC1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1291557204, COSV57250646, COSV57252095; called by muse, mutect2
- RAD21 | c.1005G>C p.K335N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52056284; called by muse, mutect2, varscan2
- RB1 | c.2483del p.R828Nfs*5 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as COSV57296585; called by mutect2, pindel, varscan2
- RGS7 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58531145; called by muse, mutect2, varscan2
- RPL26 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV53446771; called by muse, mutect2, varscan2
- RXRA | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62683548; called by muse, mutect2, varscan2
- SHOX2 | c.874G>A p.D292N (on ENST00000441443 / NM_006884.3; = p.D316N on NM_003030.4) | Missense Mutation (SNP) | VAF 86/643 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.135); catalogued as rs1338678786, COSV67463530; called by muse, mutect2, varscan2
- SLC22A12 | c.1618C>T p.H540Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV55447402; called by muse, mutect2, varscan2
- SLC22A23 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV66676637; called by muse, mutect2
- SLC45A4 | c.955G>A p.D319N (on ENST00000517878 / NM_001286646.2; = p.D268N on NM_001080431.2) | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.357); catalogued as COSV50133254; called by muse, mutect2, varscan2
- SORCS3 | c.2813G>C p.W938S | Missense Mutation (SNP) | VAF 93/110 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100863793, COSV63793449; called by muse, mutect2, varscan2
- SVEP1 | c.1847C>G p.P616R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57029401; called by muse, mutect2, varscan2
- TBK1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1555204111, CM153994, COSV59153532; called by muse, mutect2, varscan2
- TOP1MT | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375561204; called by muse, mutect2, varscan2
- TPP2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65751056; called by muse, mutect2, varscan2
- TTN | c.80078A>G p.D26693G (on ENST00000591111; = p.D19269G on NM_003319.4) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | PolyPhen benign (0.001); catalogued as COSV59895404; called by muse, mutect2, varscan2
- TTN | c.8809C>T p.Q2937* (on ENST00000591111; = p.Q2891* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 53/251 reads (21%) | catalogued as COSV100625362; called by muse, mutect2, varscan2
- UCP2 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV60104291, COSV60105035; called by muse, mutect2, varscan2
- UTP4 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs774735552, COSV58732090; called by muse, mutect2, varscan2
- WDFY3 | c.7962-1G>A p.X2654_splice | Splice Site (SNP) | VAF 31/131 reads (24%) | catalogued as COSV55693655; called by muse, mutect2, varscan2
- XAB2 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.4); catalogued as COSV50330922; called by muse, mutect2, varscan2
- XRN2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907978875, COSV65869238; called by muse, mutect2
- ZCWPW2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67497577; called by muse, mutect2, varscan2
- ZDBF2 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV65621999, COSV65627284; called by muse, mutect2, varscan2
- ZIC1 | c.763C>A p.H255N | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51550691; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV60155611; called by muse, mutect2, varscan2
- ZNF445 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs891552972, COSV68538441; called by muse, mutect2, varscan2
- ZNF468 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54693345; called by muse, mutect2, varscan2
- ZNF492 | c.1333G>T p.G445* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV101514038; called by muse, mutect2, varscan2
- ZNF492 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV71761681; called by muse, mutect2, varscan2
- ZNF548 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60240326; called by muse, mutect2, varscan2
- ZSCAN10 | c.1616C>T p.A539V (on ENST00000252463; = p.A594V on NM_032805.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as rs1314910385; called by muse, mutect2
- ZYX | c.1207C>G p.Q403E | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV51968596; called by muse, varscan2
- ABO | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- AUP1 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- CTSC | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DLD | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2
- GET3 | c.554_558del p.R185Pfs*54 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- RESF1 | c.2306C>A p.S769* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- TSPAN12 | c.337_341del p.W113Ifs*2 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- TXNIP | c.499_502del p.K167Ffs*63 | Frame Shift Del (DEL) | VAF 115/685 reads (17%) | called by pindel, varscan2
- ZNF341 | c.479del p.P160Hfs*7 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.691C>T p.L231= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV63203240; called by muse, mutect2, varscan2
- CALCR | c.1251C>T p.T417= (on ENST00000649521 / NM_001164737.2; = p.T401= on NM_001742.4) | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs756884648, COSV64005979; called by muse, mutect2, varscan2
- CARD14 | c.2784C>T p.N928= | Silent (SNP) | VAF 44/72 reads (61%) | catalogued as rs140536892; called by muse, mutect2, varscan2
- CD1E | c.411C>T p.F137= | Silent (SNP) | VAF 43/311 reads (14%) | catalogued as COSV63770018, COSV63770734; called by muse, mutect2, varscan2
- CD34 | c.327T>C p.S109= | Silent (SNP) | VAF 135/204 reads (66%) | catalogued as COSV60411769; called by muse, mutect2, varscan2
- CD40 | c.612C>A p.I204= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV64847496; called by muse, mutect2, varscan2
- CFAP97 | c.231A>G p.P77= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV57109210; called by muse, mutect2, varscan2
- COL20A1 | c.1782C>T p.S594= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs774401193, COSV58911947; called by muse, mutect2, varscan2
- COL4A6 | c.1410A>T p.L470= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as COSV57859575; called by muse, mutect2, varscan2
- CREBRF | c.690A>G p.E230= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as rs1419954939, COSV51631317; called by muse, mutect2, varscan2
- DISP1 | c.2697G>A p.R899= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV52654854; called by muse, mutect2, varscan2
- DIXDC1 | c.873A>G p.L291= (on ENST00000440460 / NM_001037954.4; = p.L80= on NM_033425.4) | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- ETV4 | c.87C>A p.R29= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV60043729; called by muse, mutect2, varscan2
- EVX1 | c.1104G>A p.S368= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV56084779; called by muse, mutect2, varscan2
- FMNL3 | c.1842G>A p.A614= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs778622208, COSV53298096; called by muse, mutect2, varscan2
- GRIK3 | c.1191G>T p.L397= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100902384, COSV66135743; called by muse, mutect2, varscan2
- GRIN2D | c.1668C>T p.F556= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs1213091832, COSV54377071; called by muse, mutect2, varscan2
- GRM7 | c.474G>A p.G158= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs757826887, COSV63129934; called by muse, mutect2, varscan2
- GRXCR1 | c.85C>T p.L29= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV101295654, COSV67670157; called by muse, mutect2, varscan2
- HERC2 | c.6975C>T p.I2325= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV55308124; called by muse, mutect2, varscan2
- INO80D | c.1782G>A p.L594= | Silent (SNP) | VAF 10/197 reads (5%) | catalogued as COSV68958127, COSV68960366; called by muse, mutect2
- KIF4A | c.3030C>T p.T1010= | Silent (SNP) | VAF 45/52 reads (87%) | catalogued as COSV65541440; called by muse, mutect2, varscan2
- KLHL26 | c.1035G>A p.T345= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs745953555, COSV56316247; called by muse, mutect2, varscan2
- LRRC40 | c.1497G>A p.T499= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1291749296, COSV63941600; called by muse, mutect2, varscan2
- MYT1L | c.63G>A p.V21= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV67708721; called by muse, varscan2
- MZF1 | c.1776G>T p.T592= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV53040698; called by muse, mutect2, varscan2
- NLRP12 | c.435G>T p.A145= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV100145930, COSV60743750; called by muse, mutect2, varscan2
- OR1A1 | c.870G>A p.L290= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as COSV58403149; called by muse, mutect2
- OR51A4 | c.861G>A p.L287= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV66749064; called by muse, mutect2, varscan2
- OR5B17 | c.282C>T p.A94= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV62159904; called by muse, mutect2, varscan2
- PHLPP2 | c.3966A>T p.A1322= | Silent (SNP) | VAF 54/83 reads (65%) | catalogued as COSV62422611; called by muse, mutect2, varscan2
- PRAMEF7 | c.1305G>A p.E435= | Silent (SNP) | VAF 40/309 reads (13%) | catalogued as rs996690856; called by muse, mutect2, varscan2
- SAE1 | c.132G>A p.L44= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV54293290; called by muse, mutect2, varscan2
- SCN9A | c.3408A>G p.G1136= (on ENST00000303354; = p.G1125= on NM_002977.3) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV57600710; called by muse, mutect2, varscan2
- SOX5 | c.957C>A p.I319= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV58618883; called by muse, mutect2, varscan2
- SPATA20 | c.1551T>C p.A517= (on ENST00000356488 / NM_001258372.1; = p.A533= on NM_022827.4) | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV50065830; called by muse, mutect2, varscan2
- SUPT6H | c.2394G>T p.L798= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV58924668; called by muse, mutect2, varscan2
- SUSD4 | c.189C>T p.P63= | Silent (SNP) | VAF 49/83 reads (59%) | catalogued as rs577114146, COSV59549914; called by muse, mutect2, varscan2
- SYNE1 | c.14115C>T p.A4705= (on ENST00000367255 / NM_182961.4; = p.A4634= on NM_033071.3) | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as rs377739292; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TRPM8 | c.2157G>A p.K719= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV100223889, COSV61220686; called by muse, mutect2
- VEZT | c.333G>T p.L111= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as COSV54136033; called by muse, mutect2, varscan2
- ZNF112 | c.2142C>T p.V714= (on ENST00000337401 / NM_001083335.2; = p.V708= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV61618817; called by muse, mutect2, varscan2
- ZNF792 | c.1645C>T p.L549= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV68692744; called by muse, mutect2, varscan2
- MIR1197 | n.23G>A | RNA (SNP) | VAF 14/32 reads (44%) | catalogued as rs141611518; called by muse, mutect2, varscan2
- RARB | chr3:25596473 C>G | 3'Flank (SNP) | VAF 43/187 reads (23%) | catalogued as COSV51968704, COSV99979203; called by muse, mutect2, varscan2
- SNORD116-3 | n.54G>A | RNA (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- SSPOP | n.10927G>A | RNA (SNP) | VAF 15/60 reads (25%) | catalogued as rs368962833; called by muse, mutect2, varscan2
- Z82190.2 | c.1787-21941G>A | Intron (SNP) | VAF 18/23 reads (78%) | catalogued as rs763209664, COSV50734660; called by muse, mutect2, varscan2
